TARGET case TARGET-30-PAKUAW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/cdaeee23-d927-5618-9825-0f3ead898b8b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 1.1 years (416 days); Year of diagnosis: 2001; Days to last follow up: 61 days; INSS stage: Stage 1.

Biospecimens (2 samples)
- Sample TARGET-30-PAKUAW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAKUAW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
